Gene-level copy-number profile of tumor specimen TCGA-CG-4438-01A from TCGA case TCGA-CG-4438, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,574 days).
Specimen TCGA-CG-4438-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.bc7a8bf2-f637-4822-bdbb-7131203a0a02.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4438-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3137a399-5028-4889-9762-d88c218e5071

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 2,732; copy number 2: 24,874; copy number 3: 18,448; copy number 4: 9,442; copy number 5: 2,555; copy number 6: 109; copy number 7: 1,516; copy number 8: 8; copy number 10: 3; copy number 11: 14; copy number 13: 5; copy number 18: 10; copy number 20: 9; copy number 23: 4; copy number 26: 27; copy number 27: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4438-01A-01D-1155-01): tumor purity 0.66, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,310 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:12,794,100–44,700,808, 454 genes, copy number 5–7 (broad region; genes not listed).
- chr5:63,957,874–65,871,725, 28 genes, copy number 5: HTR1A, AC122707.1, RNF180, AC091862.1, RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1, SHISAL2B, SREK1IP1, CWC27, AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1, TRIM23, RNU6-540P, TRAPPC13, SHLD3, SGTB, NLN, AC008958.1.
- chr7:38,256,337–38,300,322, 8 genes, copy number 8: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:91,638,847–94,077,157, 50 genes, copy number 11–26: AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2.
- chr7:114,560,961–118,513,830, 69 genes, copy number 18–27 (broad region; genes not listed).
- chr8:55,102,028–88,887,573, 503 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:89,826,593–145,066,685, 891 genes, copy number 5 (broad region; genes not listed).
- chr10:61,901,684–62,096,944, 1 gene, copy number 5: ARID5B.
- chr13:18,467,172–26,698,804, 213 genes, copy number 5 (broad region; genes not listed).
- chr13:39,009,865–67,379,994, 404 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr14:22,132,553–22,496,952, 51 genes, copy number 5: TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42.
- chr15:60,347,134–60,409,420, 4 genes, copy number 5: ANXA2, AC087385.1, AC087385.2, AC087385.3.
- chr16:14,301,389–20,576,427, 182 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:87,250–16,053,197, 290 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr20:15,552,157–64,313,132, 1,162 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,272. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
